Somatic mutation profile of tumor specimen TCGA-RC-A7SF-01A (aliquot TCGA-RC-A7SF-01A-11D-A34Z-10) from TCGA case TCGA-RC-A7SF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.9 years (24,432 days).
Specimen TCGA-RC-A7SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9690fc97-4349-4d54-968b-18db038ba05b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A7SF-10A (Blood Derived Normal), aliquot TCGA-RC-A7SF-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2656c771-8674-4642-be15-aa6b18c57c6f

The open-access MAF lists 86 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 58, Silent 18, Frame Shift Del 5, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886044202, CM081489, COSV55595323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC3 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV53325182; called by muse, mutect2, varscan2
- ANK1 | c.3052A>G p.K1018E | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV55886805; called by mutect2, varscan2
- AQP11 | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as COSV57992789; called by muse, mutect2, varscan2
- ATP10D | c.2599A>T p.S867C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56709809; called by muse, varscan2
- BVES | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs748009650, COSV58948791; called by muse, mutect2, varscan2
- CA11 | c.393T>A p.S131R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV50033513; called by muse, mutect2, varscan2
- CABIN1 | c.6256G>A p.A2086T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV54085167; called by muse, varscan2
- CACNA1I | c.3635C>A p.T1212K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60813262; called by muse, mutect2, varscan2
- CADPS | c.3046C>A p.P1016T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as COSV51890175; called by muse, mutect2, varscan2
- CCAR2 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV100414923, COSV57906626; called by muse, mutect2, varscan2
- CCDC137 | c.349_350del p.R117Efs*5 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs754471106; called by pindel, varscan2
- CCN3 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV52384506; called by muse, mutect2, varscan2
- CD300C | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58170960; called by muse, mutect2, varscan2
- CD68 | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV51511415; called by muse, mutect2, varscan2
- CDKN1A | c.137del p.R46Lfs*102 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV55188273, COSV55188826, COSV99781273; called by pindel, varscan2
- CFAP70 | c.3341T>C p.V1114A | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs781065003, COSV60284933; called by muse, mutect2, varscan2
- CFAP91 | c.2093T>C p.V698A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56342537, COSV56344281; called by muse, mutect2, varscan2
- CHRNA1 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53683954; called by muse, mutect2, varscan2
- CILP2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV52277344; called by muse, mutect2, varscan2
- E2F7 | c.1193A>C p.Q398P | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV59741626; called by muse, mutect2, varscan2
- EGF | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54481229; called by muse, mutect2, varscan2
- ENOX2 | c.539A>G p.Y180C (on ENST00000338144 / NM_001382520.1; = p.Y151C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1366010885, COSV57654574; called by muse, mutect2, varscan2
- FAM135A | c.3965+1G>T p.X1322_splice (on ENST00000370479 / NM_001351599.1; = p.X1109_splice on NM_020819.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV52054830; called by muse, mutect2, varscan2
- FYCO1 | c.3542A>G p.D1181G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.324); catalogued as rs764117873, COSV56117529; called by muse, mutect2, varscan2
- IL7 | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 80/649 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV55676274; called by muse, mutect2, varscan2
- ITM2A | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV64811355; called by muse, mutect2, varscan2
- JUNB | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV56878300; called by muse, mutect2, varscan2
- KIAA1522 | c.716G>T p.R239L (on ENST00000373480 / NM_001198972.2; = p.R298L on NM_020888.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV53866043; called by muse, mutect2, varscan2
- KIF1A | c.3955G>A p.G1319R (on ENST00000320389 / NM_001379639.1; = p.G1311R on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs926294483, COSV57494523; called by muse, mutect2, varscan2
- KRT6B | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52884893; called by muse, mutect2, varscan2
- LIPC | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54424603; called by muse, mutect2, varscan2
- LYL1 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV53400403; called by muse, mutect2, varscan2
- MACF1 | c.702C>A p.H234Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV58385466; called by muse, mutect2, varscan2
- NBEAL1 | c.5030G>T p.C1677F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV71374938; called by muse, mutect2, varscan2
- NEK10 | c.3502C>T p.H1168Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55361026; called by muse, mutect2, varscan2
- NFAT5 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63029627; called by muse, mutect2, varscan2
- NME8 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV52252751; called by muse, mutect2, varscan2
- NSD1 | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61779283; called by muse, mutect2, varscan2
- OR13D1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs182904893; called by muse, mutect2, varscan2
- PDE8A | c.298T>A p.C100S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV59638580; called by muse, mutect2, varscan2
- PDE8A | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59634823, COSV59638589; called by muse, mutect2, varscan2
- PDZRN3 | c.1087A>C p.T363P | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760956222, COSV55206918; called by muse, mutect2, varscan2
- POR | c.659T>A p.I220N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101203553; called by muse, mutect2, varscan2
- POR | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.393); catalogued as COSV101203554; called by muse, mutect2, varscan2
- PRKCQ | c.1182C>A p.V394= | Splice Region (SNP) | VAF 7/97 reads (7%) | catalogued as COSV54114566; called by muse, mutect2
- PRX | c.3875A>T p.Q1292L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52522729; called by muse, mutect2, varscan2
- PTPRT | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61997681; called by muse, mutect2, varscan2
- RAB3GAP2 | c.130T>G p.W44G | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV52966473; called by muse, mutect2, varscan2
- SHKBP1 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52541575; called by muse, mutect2
- SHROOM3 | c.4577T>G p.L1526R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV56033939; called by muse, mutect2, varscan2
- SPCS3 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV72419088; called by muse, mutect2, varscan2
- SPRY2 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV65701577; called by muse, mutect2, varscan2
- SPTBN5 | c.8608C>T p.R2870W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs367976253; called by mutect2, varscan2
- TMEM106B | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as rs768078337, COSV67543339; called by muse, mutect2, varscan2
- TMEM45A | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV60254557; called by muse, mutect2, varscan2
- TMEM63B | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52480765; called by muse, mutect2, varscan2
- TPM1 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as COSV51263568; called by muse, varscan2
- TTC38 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs370933560; called by muse, mutect2, varscan2
- TTLL4 | c.2833A>G p.I945V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749737475, COSV51437621; called by muse, mutect2, varscan2
- UBQLN3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs201719446, COSV61164777; called by muse, mutect2, varscan2
- ZBTB14 | c.274T>A p.Y92N | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63696999; called by muse, mutect2, varscan2
- ZNF708 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as COSV63607965; called by muse, mutect2, varscan2
- CDKN1A | c.49del p.A17Pfs*14 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by pindel, varscan2
- FRG2C | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NYAP2 | c.266del p.G89Afs*9 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- PCLO | c.7633_7642del p.N2545Lfs*34 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- TMEM129 | c.261_269del p.Q88_P90del | In Frame Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CYP2A13 | c.297C>T p.S99= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs777323292, COSV57838886; called by muse, mutect2, varscan2
- IDE | c.1110T>C p.F370= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV56425096; called by muse, mutect2, varscan2
- KIF5A | c.237T>C p.N79= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV54056459; called by muse, varscan2
- KRT6B | c.441C>A p.P147= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV52884881; called by muse, mutect2, varscan2
- PCP4L1 | c.184A>C p.R62= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV73440722; called by muse, mutect2, varscan2
- PHRF1 | c.600C>G p.L200= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52758737; called by muse, mutect2, varscan2
- ROR1 | c.1779G>T p.L593= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV64289693; called by muse, varscan2
- SC5D | c.600G>A p.L200= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs868778899, COSV50613295; called by muse, mutect2, varscan2
- SOX10 | c.279C>A p.R93= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV61005704; called by muse, mutect2, varscan2
- TBL1X | c.1287C>G p.S429= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as rs1437186339, COSV54283646; called by muse, mutect2, varscan2
- THAP12 | c.711G>A p.Q237= | Silent (SNP) | VAF 178/256 reads (70%) | catalogued as COSV52611539; called by muse, mutect2, varscan2
- TLL1 | c.1974G>A p.V658= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs891909769, COSV50303480; called by muse, mutect2, varscan2
- TRIM56 | c.1614C>T p.G538= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs753220033, COSV60157048; called by muse, mutect2, varscan2
- USF1 | c.399G>T p.S133= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs781322237, COSV57039063; called by muse, mutect2, varscan2
- USP42 | c.1005T>A p.P335= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV60362014; called by muse, mutect2, varscan2
- XIRP2 | c.4974A>G p.K1658= (on ENST00000628543; = p.K1833= on NM_152381.6) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54715197; called by muse, mutect2
- XPNPEP1 | c.975C>T p.L325= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV59169556; called by muse, mutect2, varscan2
- ZNF438 | c.2202G>A p.Q734= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV59197637; called by muse, mutect2, varscan2
